Surgical pathology report (de-identified scan), TCGA case TCGA-YC-A9TC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Spectrum Health, specimen TCGA-YC-A9TC-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

-year-old male, bladder TURB

Research Dx

Bladder tumor, transurethral resection:

Urothelial carcinoma with extensive squamous differentiation. See case summary and comment.

CASE SUMMARY FOR URINARY BLADDER BIOPSY AND TRANSURETHRAL RESECTION OF BLADDER TUMOR (TURBT):

Procedure: TURBT

Tumor type: Invasive carcinoma

Histologic type: Urothelial carcinoma with extensive squamous differentiation

Associated epithelial lesions: None identified

Histologic grade (WHO/ISUP): High grade

Tumor configuration: Solid and papillary

Adequacy of material for determining muscularis propria invasion: Muscularis propria present

Lymph-vascular invasion: Present

Microscopic tumor extension: Tumor invades muscularis propria

Additional pathologic findings: Keratinizing squamous metaplasia, extensive necrosis and calcification

AJCC Staging (7th edition): At least pT2 pNX pM:Not applicable

Research QC

Original Tumor T1:

90% tumor nuclei 1/3 squamous, 2/3 poorly differentiated; 0% necrosis;

10% normal stroma

Re-review/Revised:

80% tumor nuclei 1/3 squamous, 2/3 poorly differentiated; 10% necrosis;

10% normal stroma

Normal:

na

ICD-O-3
Carcinoma, urothelial NOS
8120/3

Research Specimen

-

Site Bladder NOS
C67.9
9/11/14

Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Tissue:

Cold ischemia start time:

Formalin fixation start time:

Frozen start time:

Total cold ischemia time: 22 minutes

Formalin fixation stop time:

Total formalin fixation time: The specimen has spent greater than 6 and fewer than 72 hours in formalin.

Specimen Weight

[page 2 of 2]
Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 1

Normal x 0

Tumor x 1 - 1.475 mg

Metastatic x 0

FFPE x 1

Normal x 0

Tumor x 1

Metastatic x 0

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file c934968f-00de-4f4c-a977-0dcd68f2227a (TCGA-YC-A9TC.DA4F1C21-0B25-452C-BBC4-B27ECE0216F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).